Gene-level copy-number profile of tumor specimen C3L-02130-01 from CPTAC case C3L-02130, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 70.9 years (25,907 days).
Specimen C3L-02130-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 52f9b9aa-5ed1-4a40-9d42-e15c7ae32066.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-02130-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/80d05676-ebc1-4d98-9623-dffcf3ab7d4c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 553; copy number 1: 14,476; copy number 2: 38,753; copy number 3: 4,034; copy number 4: 621; copy number 5: 187; copy number 6: 38; copy number 7: 71; copy number 8: 124; copy number 9: 10; copy number 14: 3; copy number 16: 38.

Homozygous deletions (total copy number 0; autosomes only): 36 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:64,369,394–64,413,142, 2 genes: ANKRD20A4P, RNU6-1193P.
- chr19:4,360,370–4,445,018, 4 genes (within-gene range 0–1): SH3GL1, AC007292.1, CHAF1A, AC011498.3.
- chr19:20,416,514–20,571,095, 3 genes (within-gene range 0–1): BNIP3P22, AC008554.1, BNIP3P23.
- chr21:7,744,962–8,454,792, 26 genes: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1.
- chr21:8,680,538–8,680,934, 1 gene: CR381572.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 471 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:61,605,616–62,662,829, 27 genes, copy number 5: RNU6-1145P, AC108039.1, RPS24P7, AC108039.2, FAM161A, RPL31P30, AC107081.2, CCT4, AC107081.1, AC107081.3, COMMD1, Y_RNA, AC018462.1, RPSAP26, AC018462.2, B3GNT2, MIR5192, RN7SL51P, AC093159.2, AC093159.1, RN7SL18P, TMEM17, RPL37P13, RPL21P37, AC092155.1, PSAT1P2, RSL24D1P2.
- chr2:69,396,113–69,674,349, 4 genes, copy number 5 (within-gene range 2–5): NFU1, AAK1, RN7SL604P, SNORA36C.
- chr4:45,995,119–47,426,447, 10 genes, copy number 6: RN7SKP199, GABRG1, AC104072.1, GABRA2, AC095060.1, RNU6-412P, RAC1P2, COX7B2, GABRA4, GABRB1.
- chr4:52,252,820–53,366,066, 19 genes, copy number 5: AC097522.2, AC097522.1, RNU6-1252P, USP46, USP46-DT, AC104066.3, DANCR, LINC01618, MIR4449, AC104066.4, SNORA26, AC104066.2, ERVMER34-1, AC104066.1, Y_RNA, RASL11B, SCFD2, AC023154.1, RNU6-310P.
- chr4:56,049,073–57,495,844, 38 genes, copy number 5–14: CRACD, RNA5SP161, RNU6-197P, AC022267.1, MRPL22P1, AASDH, RPL7AP31, AC068620.1, PPAT, AC068620.2, AC068620.3, PAICS, SRP72, ARL9, THEGL, GLDCP1, HOPX, AC108215.1, RPL17P20, AC022483.1, RN7SL492P, RN7SL357P, SPINK2, Metazoa_SRP, Y_RNA, REST, AC069307.1, NOA1, POLR2B, RNU6-998P, IGFBP7, UBE2CP3, IGFBP7-AS1, AC111197.1, AC105390.1, RPS26P24, LINC02380, AC013724.1.
- chr9:64,462,819–64,463,196, 1 gene, copy number 5: CR769776.2.
- chr9:64,621,560–64,765,535, 5 genes, copy number 5–6: AQP7P2, AL445665.1, BMS1P11, AL359955.2, IGKV1OR-2.
- chr11:55,262,155–56,971,979, 121 genes, copy number 5–8 (broad region; genes not listed).
- chr11:68,941,503–70,896,305, 55 genes, copy number 7–16: AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, AP003783.1.
- chr14:29,210,986–30,373,115, 12 genes, copy number 5–9: AL133166.1, AL158058.1, AL158058.2, RNU11-5P, PRKD1, AL356756.1, RNU6-1234P, AL355053.1, AL133372.3, AL133372.2, AL133372.1, AL079305.1.
- chr14:33,924,227–34,462,774, 1 gene, copy number 8 (within-gene range 4–8): EGLN3.
- chr14:34,416,687–38,041,442, 90 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).
- chr14:57,993,545–58,648,321, 24 genes, copy number 8: AL049838.1, ARMH4, AL121579.2, UBA52P3, RN7SL598P, AL121579.1, ACTR10, PSMA3, AL132989.1, PSMA3-AS1, HMGB1P14, LINC00216, RNU6-341P, ARID4A, AL139021.2, TOMM20L, AL139021.1, TIMM9, KIAA0586, Y_RNA, HSBP1P1, HNRNPCP1, RPL9P5, DACT1.
- chr14:60,709,539–61,550,976, 12 genes, copy number 8 (within-gene range 4–8): SIX4, MNAT1, MAD2L1P1, AL160236.2, SRMP2, TRMT5, AL160236.1, RNU6-398P, SLC38A6, PRKCH, TMEM30B, AL359220.1.
- chr14:81,441,987–81,533,853, 2 genes, copy number 6: LINC02308, SEL1L.
- chr14:90,256,527–90,491,637, 10 genes, copy number 5–6: PSMC1, NRDE2, AL161662.1, RPL21P11, AL512791.2, CALM1, AL512791.1, LINC02317, LINC00642, AL096869.3.
- chr14:93,718,298–94,593,118, 24 genes, copy number 7 (within-gene range 4–7): PRIMA1, AL132642.2, FAM181A-AS1, FAM181A, ASB2, AL132642.1, MIR4506, CCDC197, OTUB2, DDX24, IFI27L1, IFI27, IFI27L2, PPP4R4, SERPINA10, SERPINA6, SERPINA2, SERPINA1, AL132708.1, SERPINA11, SERPINA9, SERPINA12, SERPINA4, SERPINA5.
- chr14:98,068,161–98,205,143, 2 genes, copy number 6: AL163932.1, LINC02295.
- chr19:40,121,311–40,380,439, 14 genes, copy number 6 (within-gene range 2–6): VN1R96P, MAP3K10, TTC9B, CCNP, AKT2, AC118344.1, MIR641, RNU6-945P, C19orf47, Y_RNA, Y_RNA, PLD3, AC118344.2, MIR6796.

Autosomal genes at a single copy (total copy number 1): 12,142. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
